Surgical pathology report (de-identified scan), TCGA case TCGA-19-0963, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-0963-01B (Primary Tumor).

[page 1 of 2]
**SURGICAL PATHOLOGY REPORT**

FINAL DIAGNOSIS

- A. LEFT BRAIN CYSTIC TUMOR, REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: The tumor demonstrates focal circumscription with pilomyxoid degeneration. Necrosis is not identified, however, microvascular proliferation is prominent.

- B. SPECIMEN LABELED CYST WALL, BIOPSY:
-- GLIOBLASTOMA MULTIFORME.

Note: Immunohistochemical stains confirm the diagnosis.

- C. TEMPORAL TIP, BIOPSY:
-- CEREBRAL CORTEX DEMONSTRATING MILD ASTROCYTIC HYPERCELLULARITY.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A & B: Touch Imprint: High grade glioma.

Clinical History:

Left brain cystic lesion

Specimens Submitted As:

A: TUMOR
B: CYST WALL
C: TEMPORAL TIP

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, are multiple, irregular fragments of tan-brown and gray, soft tissue, measuring approximately 3.5 x 3 x 1.5 cm. A touch imprint and frozen section is performed on this tissue. The entire specimen is submitted in total of five cassettes.

[page 2 of 2]
B: Received fresh for intraoperative consultation, labelled with the patient's name and number, are multiple, irregular fragments of tan-brown and gray, soft tissue, measuring approximately 1.5 x 1 x 0.4 cm in aggregate. A touch imprint and frozen section are performed on the specimen, and the entire specimen is submitted in two cassettes.

C: Received fresh for intraoperative consultation, are multiple, irregular fragments of tan-gray, soft tissue, measuring approximately 1.5 x 0.8 x 0.4 cm in aggregate. A frozen section and touch imprint were performed and submitted in one cassette.

Summary of Cassettes:

A	1FS	
	2-5	remainder of the specimen
B	1FS	
	2	remainder of the specimen
C	1	entire specimen of tan-gray, soft tissue

Source: NCI Genomic Data Commons file c6cb32ab-0cfe-4d7b-b729-62ce8365018d (TCGA-19-0963.49671C76-94C6-4EBD-9397-2340DAD64F6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).